TCGA case TCGA-4W-AA9T — Glioblastoma Multiforme (TCGA-GBM)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Gliomas; Primary site: Brain; Tissue source site: University of Miami. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/998c8517-89c1-43b2-84e4-b60905787bf6

Demographics
Sex at birth: female; Race: black or african american; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 54 years; Vital status: Alive.

Diagnoses (2)
1. Glioblastoma (the primary disease): ICD-O-3 morphology code: 9440/3; ICD-10 code: C71.9; Tissue or organ of origin: Brain, NOS; Site of resection or biopsy: Brain, NOS; Classification of tumor: primary; Age at diagnosis: 54.2 years (19,801 days); Year of diagnosis: 2012; Method of diagnosis: Surgical Resection; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No.
   Pathology details: Consistent pathology review: Yes.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Temozolomide; Days to treatment start: 36 days; Treatment outcome: Treatment Ongoing.
   Treatment given: Treatment type: Radiation Therapy, NOS; Days to treatment start: 79 days; Days to treatment end: 79 days; Treatment outcome: Complete Response.
2. Diagnosis record without a diagnosis name: Tumor of origin: diagnosis 1 of this record; Age at diagnosis: 56.3 years (20,550 days); Days to diagnosis: 749 days (2.1 years); Prior treatment: Yes.
   Recorded as not given: Radiation Therapy, NOS.

Follow-up (4 entries)
- Days to follow up: 449 days (1.2 years); Disease response: Tumor Free.
- Day 749 (post initial treatment): Progression or recurrence: Yes.
- Days to follow up: 778 days (2.1 years); Disease response: Tumor Free.
- Karnofsky performance status: 70; ECOG performance status: 1; Timepoint: Post Adjuvant Therapy.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-4W-AA9T-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT; Initial weight: 800 mg.
  Slide TCGA-4W-AA9T-01A-01-TSA: Section location: Top; Percent tumor cells: 50; Percent tumor nuclei: 90; Percent normal cells: 10; Percent necrosis: 0; Percent stromal cells: 40; Percent lymphocyte infiltration: 2; Percent monocyte infiltration: 2; Percent neutrophil infiltration: 0.
  Slide TCGA-4W-AA9T-01A-02-TSB: Section location: Top; Percent tumor cells: 30; Percent tumor nuclei: 90; Percent normal cells: 5; Percent necrosis: 40; Percent stromal cells: 25; Percent lymphocyte infiltration: 2; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-4W-AA9T-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-4W-AA9T-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Histologic diagnosis: Glioblastoma Multiforme (GBM); History lgg diagnosis of brain tissue: No; Prospective collection: No; Retrospective collection: Yes; Tumor status: Tumor free; History neoadjuvant treatment: No; Method initial path diagnosis: Tumor resection; Treatment outcome first course: Progressive Disease; Performance status timing: Post-Adjuvant Therapy.
- Follow-up form: Lost to follow-up: No; Treatment outcome first course: Progressive Disease; Treatment outcome at TCGA followup: Progressive Disease; Tumor status: Tumor free; New tumor event diagnosis indicator: Yes.
- Follow-up form, New tumor event: New tumor event radiation treatment: No.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 778 days; disease-specific survival: no event (censored), 778 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 749 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-4W-AA9T-01A-11D-A390-01): tumor purity 0.55, ploidy 1.98, whole-genome doublings 0.
